CCDI case PBCNBA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/fbcaebb9-b9ca-4e08-9d73-f5223397e375

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 5.5 years (2,020 days).

Biospecimens (3 samples)
- Samples 0DVSBN, 0DVSBW (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVSC8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
